Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6950, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6950-01A (Primary Tumor).

DIAGNOSIS :

- (A) LARYNX, BASE OF TONGUE AND BILATERAL FUNCTIONAL NECK DISSECTION:
INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED.
Hyoid bone, fragment of bone, no tumor present.

DIAGNOSIS

- (A) LARYNX, BASE OF TONGUE AND BILATERAL FUNCTIONAL NECK DISSECTION:
SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED (5 X 4.5 X 1.7 CM) INVOLVING THE BASE OF TONGUE, EPIGLOTTIS AND SUPRAGLOTTIC MUCOSA AND PRE-EPIGLOTTIC SPACE.
INVASION UP TO 1.7 CM OF A TOTAL 1.8 CM.
TUMOR INVOLVES LEFT LATERAL PHARYNGEAL MARGIN.
TUMOR INVOLVES TENDONOUS INSERTION ON ANTERIOR SURFACE OF SOFT TISSUE RESECTION MARGIN.
TUMOR CLOSELY APPROACHES THE ANTERIOR SOFT TISSUE MARGIN OF RESECTION (LESS THAN 0.1 CM).
No unequivocal lymphovascular invasion identified.
METASTATIC SQUAMOUS CARCINOMA INVOLVING 1 OF 25 (1/25)
RIGHT NECK LYMPH NODES (1/4 GROUP 3 LYMPH NODES WITH THE SINGLE POSITIVE LYMPH NODE MEASURING 4.0 CM IN GREATEST DIMENSION WITH AT LEAST 1.2 CM OF EXTRANODAL EXTENSION; 0/2, GROUP 4 LYMPH NODES; 0/0, GROUP 5 LYMPH NODE; 0/6, GROUP 6 LYMPH NODES; 0/8, GROUP 7 LYMPH NODES; 0/7, GROUP 8 LYMPH NODES).
METASTATIC SQUAMOUS CARCINOMA INVOLVING 2 OF 20 (2/20) LEFT NECK LYMPH NODES (1/6 GROUP 3 LYMPH NODES WITH THE METASTATIC FOCUS MEASURING APPROXIMATELY 5 MM WITH 4 MM OF EXTRANODAL EXTENSION; 1/1, GROUP 4 LYMPH NODE WITH THE METASTATIC FOCUS MEASURING 3.0 CM WITH GREATER THAN 1.0 CM OF EXTRANODAL EXTENSION; 0/0, GROUP 5, LYMPH NODES; 0/5, GROUP 6 LYMPH NODES; 0/3, GROUP 7 LYMPH NODES AND 0/5 GROUP 8 LYMPH NODES).
Right and left submandibular glands, no tumor present.
- (B) NEW LEFT LATERAL PHARYNGEAL MARGIN:
Squamous mucosa, no tumor present.
- (C) TENDON, EXCISION:
Soft tissue, no tumor present.

Source: NCI Genomic Data Commons file 62c406c4-f037-41a3-946b-465f00734691 (TCGA-CV-6950.6F050E5F-08C0-4B34-B98D-952B6FFA009D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).